Somatic mutation profile of tumor specimen HCM-WCMC-0671-C18-86A (aliquot HCM-WCMC-0671-C18-86A-01D-A937-36) from HCMI case HCM-WCMC-0671-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 47.4 years (17,322 days).
Specimen HCM-WCMC-0671-C18-86A: Sample type: Expanded Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3f874121-3dcc-4316-8b4a-399dca9494b7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-WCMC-0671-C18-10A (Blood Derived Normal), aliquot HCM-WCMC-0671-C18-10A-01D-A85C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a9912c4b-c8cf-454b-ab8e-33697469f704

The open-access MAF lists 122 somatic variants for this specimen: 80 protein-altering or splice-affecting, 39 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 72, Silent 39, Nonsense Mutation 3, Frame Shift Del 2, 3'UTR 1, 5'Flank 1, RNA 1, Splice Region 1, In Frame Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 349/518 reads (67%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.582); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- MYH7 | c.5401G>A p.E1801K | Missense Mutation (SNP) | VAF 754/1255 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs397516248, CM1410901, COSV100806734; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 368/369 reads (100%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, varscan2
- YY1AP1 | c.2125G>T p.E709* (on ENST00000295566 / NM_139118.2; = p.E652* on NM_018253.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 529/744 reads (71%) | catalogued as rs1057519598, COSV55120465; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADGRG7 | c.1645G>T p.A549S | Missense Mutation (SNP) | VAF 279/438 reads (64%) | SIFT deleterious (0.04); PolyPhen benign (0.179); catalogued as COSV56295981; called by muse, mutect2, varscan2
- AP002748.5 | c.1435C>T p.R479W | Missense Mutation (SNP) | VAF 173/495 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1370913745; called by muse, varscan2
- ARHGEF19 | c.316C>A p.P106T | Missense Mutation (SNP) | VAF 270/559 reads (48%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.262); catalogued as COSV54615416, COSV54617495; called by muse, mutect2, varscan2
- BCHE | c.1378G>T p.E460* | Nonsense Mutation (SNP) | VAF 122/466 reads (26%) | catalogued as CM055098; called by muse, mutect2, varscan2
- CELSR3 | c.829C>T p.R277C | Missense Mutation (SNP) | VAF 251/766 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as COSV99375237; called by muse, varscan2
- CFTR | c.2327C>T p.S776L | Missense Mutation (SNP) | VAF 193/534 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.217); catalogued as rs397508365, CM972954; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL5A3 | c.3782C>T p.T1261M | Missense Mutation (SNP) | VAF 205/439 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.747); catalogued as rs772890229; called by muse, mutect2, varscan2
- DKK2 | c.137C>T p.T46M | Missense Mutation (SNP) | VAF 226/386 reads (59%) | SIFT tolerated (0.05); PolyPhen benign (0.288); catalogued as rs1366887020, COSV99568057; called by muse, varscan2
- DMD | c.8852G>A p.R2951H | Missense Mutation (SNP) | VAF 196/403 reads (49%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs72466567, COSV58933390; ClinVar: uncertain significance / benign; called by muse, mutect2, varscan2
- ERCC2 | c.773G>A p.R258Q | Missense Mutation (SNP) | VAF 189/582 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.011); catalogued as rs759930858, COSV55540243; called by muse, varscan2
- FAM90A1 | c.1009G>A p.A337T | Missense Mutation (SNP) | VAF 184/616 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1338068289, COSV56712500, COSV56714018; called by muse, varscan2
- FKBP7 | c.224G>A p.R75Q | Missense Mutation (SNP) | VAF 115/315 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs778701740; called by muse, varscan2
- GALNT12 | c.1156G>A p.V386I | Missense Mutation (SNP) | VAF 314/519 reads (61%) | SIFT deleterious (0); PolyPhen benign (0.437); catalogued as COSV66663311; called by muse, mutect2, varscan2
- GDPD2 | c.1217G>A p.R406H | Missense Mutation (SNP) | VAF 196/897 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs777943165; called by muse, mutect2, varscan2
- GPR158 | c.2876A>C p.Q959P | Missense Mutation (SNP) | VAF 216/599 reads (36%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs775893038; called by mutect2, varscan2
- HS3ST3A1 | c.679G>A p.A227T | Missense Mutation (SNP) | VAF 212/664 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.06); catalogued as rs750522076, COSV52372487; called by muse, varscan2
- IFT140 | c.2323G>A p.A775T | Missense Mutation (SNP) | VAF 202/594 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs771255082; called by muse, varscan2
- ITGA8 | c.172G>C p.G58R | Missense Mutation (SNP) | VAF 210/657 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV100958992; called by muse, varscan2
- KDM4D | c.1186C>T p.R396W | Missense Mutation (SNP) | VAF 194/611 reads (32%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.617); catalogued as rs781785317; called by muse, mutect2, varscan2
- KIAA1549L | c.5267C>T p.S1756L (on ENST00000321505; = p.S2053L on NM_012194.3) | Missense Mutation (SNP) | VAF 116/356 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1205996425, COSV58584314; called by muse, varscan2
- KLF5 | c.901C>T p.P301S | Missense Mutation (SNP) | VAF 606/836 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66614378, COSV66615313; called by muse, mutect2, varscan2
- KLHL38 | c.1577C>T p.T526M | Missense Mutation (SNP) | VAF 762/1070 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs373548260; called by muse, mutect2, varscan2
- MED16 | c.244G>A p.E82K | Missense Mutation (SNP) | VAF 134/496 reads (27%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.993); catalogued as rs759087690, COSV54127508; called by muse, mutect2
- MYO3A | c.4163G>T p.R1388I | Missense Mutation (SNP) | VAF 154/422 reads (36%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV56329554; called by muse, varscan2
- NEUROD1 | c.401C>T p.T134M | Missense Mutation (SNP) | VAF 179/598 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs765540175, COSV54548386; called by muse, varscan2
- NIPBL | c.2495G>A p.R832Q | Missense Mutation (SNP) | VAF 392/597 reads (66%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.087); catalogued as rs150498581, COSV99241547; called by muse, mutect2, varscan2
- NLRP6 | c.1919G>A p.R640Q | Missense Mutation (SNP) | VAF 432/702 reads (62%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs777994754, COSV56459160, COSV56459330; called by muse, varscan2
- OR2W3 | c.493C>T p.R165C | Missense Mutation (SNP) | VAF 170/712 reads (24%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.806); catalogued as rs759398397, COSV64455968; called by muse, varscan2
- OR9I1 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 141/399 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.338); catalogued as rs145179217; called by muse, mutect2, varscan2
- PPP1R2C | c.176C>T p.T59M | Missense Mutation (SNP) | VAF 160/290 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as rs779855030, COSV65363978; called by muse, varscan2
- PRELP | c.814C>T p.R272W | Missense Mutation (SNP) | VAF 714/930 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs554590706, COSV58116609; called by muse, mutect2, varscan2
- PTGER3 | c.467C>T p.A156V | Missense Mutation (SNP) | VAF 248/500 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.328); catalogued as COSV100138502, COSV60695422; called by muse, varscan2
- RAB11FIP5 | c.830G>A p.R277H | Missense Mutation (SNP) | VAF 372/625 reads (60%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs372149039, COSV50248399; called by muse, varscan2
- RBM12 | c.1350T>A p.F450L | Missense Mutation (SNP) | VAF 499/668 reads (75%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV58290226; called by muse, varscan2
- RP1L1 | c.4529C>T p.A1510V | Missense Mutation (SNP) | VAF 234/454 reads (52%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs373409421; called by muse, varscan2
- SETD3 | c.576_578del p.D192del | In Frame Del (DEL) | VAF 284/468 reads (61%) | catalogued as rs748875088; called by mutect2, pindel, varscan2
- SLC13A3 | c.1580C>T p.T527M | Missense Mutation (SNP) | VAF 54/988 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1324143927, COSV51716411; called by muse, mutect2
- SLC25A53 | c.361G>A p.G121R | Missense Mutation (SNP) | VAF 438/1090 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782336534; called by muse, varscan2
- TBC1D32 | c.795_798del p.S266Gfs*12 | Frame Shift Del (DEL) | VAF 46/248 reads (19%) | catalogued as rs759071569; called by pindel, varscan2
- TUBA3C | c.988G>A p.A330T | Missense Mutation (SNP) | VAF 527/763 reads (69%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.01); catalogued as rs1333388009, COSV104433929; called by muse, varscan2
- UBQLN3 | c.349C>T p.L117F | Missense Mutation (SNP) | VAF 179/578 reads (31%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as rs1284294682, COSV100294044; called by muse, mutect2, varscan2
- UGT2B10 | c.612G>T p.M204I | Missense Mutation (SNP) | VAF 108/262 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as COSV55322200; called by muse, mutect2, varscan2
- ZBTB33 | c.968G>T p.G323V | Missense Mutation (SNP) | VAF 346/1002 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.193); catalogued as COSV58532966; called by muse, varscan2
- ZFHX4 | c.9230C>T p.T3077M | Missense Mutation (SNP) | VAF 448/658 reads (68%) | SIFT deleterious (0.02); PolyPhen benign (0.172); catalogued as rs377249680; called by muse, mutect2, varscan2
- ZNF195 | c.914G>A p.C305Y (on ENST00000399602 / NM_001130520.3; = p.C233Y on NM_007152.5) | Missense Mutation (SNP) | VAF 138/474 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.648); catalogued as rs964710282; called by muse, mutect2, varscan2
- ZNF791 | c.1223G>A p.G408E | Missense Mutation (SNP) | VAF 55/442 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV58481025; called by muse, mutect2, varscan2
- ALOX15 | c.736C>T p.H246Y | Missense Mutation (SNP) | VAF 90/170 reads (53%) | SIFT tolerated (0.11); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- APC | c.4188del p.F1396Lfs*19 | Frame Shift Del (DEL) | VAF 154/213 reads (72%) | called by mutect2, pindel, varscan2
- ARSG | c.103A>G p.K35E | Missense Mutation (SNP) | VAF 202/422 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- ATP6V1FNB | c.116C>T p.A39V | Missense Mutation (SNP) | VAF 176/643 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- CAPS2 | c.345A>T p.K115N | Missense Mutation (SNP) | VAF 112/215 reads (52%) | SIFT tolerated (0.19); PolyPhen benign (0.007); called by muse, varscan2
- CD69 | c.558T>G p.C186W | Missense Mutation (SNP) | VAF 31/237 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CEP170 | c.1661C>A p.A554E | Missense Mutation (SNP) | VAF 153/605 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.055); called by mutect2, varscan2
- FBF1 | c.1165C>A p.L389M (on ENST00000586717; = p.L403M on NM_001319193.1) | Missense Mutation (SNP) | VAF 216/450 reads (48%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.914); called by muse, varscan2
- FBN2 | c.3677C>T p.S1226F | Missense Mutation (SNP) | VAF 157/327 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FNIP1 | c.1200C>T p.F400= | Splice Region (SNP) | VAF 68/160 reads (43%) | called by muse, mutect2, varscan2
- HECTD3 | c.310G>T p.V104L | Missense Mutation (SNP) | VAF 262/506 reads (52%) | SIFT tolerated (0.88); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HSD3B1 | c.752G>A p.G251E | Missense Mutation (SNP) | VAF 157/970 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IRX1 | c.1049C>T p.A350V | Missense Mutation (SNP) | VAF 454/710 reads (64%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, varscan2
- KCNA4 | c.442G>A p.G148S | Missense Mutation (SNP) | VAF 66/602 reads (11%) | SIFT tolerated (0.47); PolyPhen benign (0.003); called by muse, varscan2
- MINAR1 | c.1047A>T p.Q349H | Missense Mutation (SNP) | VAF 351/550 reads (64%) | SIFT tolerated (0.08); PolyPhen benign (0.001); called by muse, varscan2
- MXRA5 | c.4427C>A p.T1476N | Missense Mutation (SNP) | VAF 226/450 reads (50%) | SIFT tolerated (0.29); PolyPhen benign (0); called by mutect2, varscan2
- PCDH10 | c.2683G>T p.V895F | Missense Mutation (SNP) | VAF 144/262 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- POMT2 | c.1388T>G p.F463C | Missense Mutation (SNP) | VAF 154/593 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.176); called by muse, mutect2
- PRG4 | c.466G>T p.E156* | Nonsense Mutation (SNP) | VAF 29/424 reads (7%) | called by muse, mutect2
- PRR18 | c.707A>C p.K236T | Missense Mutation (SNP) | VAF 132/661 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, varscan2
- RNF141 | c.242T>C p.V81A | Missense Mutation (SNP) | VAF 67/438 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- SLC2A4RG | c.433_434dup p.G146Qfs*45 | Frame Shift Ins (INS) | VAF 104/786 reads (13%) | called by mutect2, pindel, varscan2
- SLC35B1 | c.707C>T p.T236I (on ENST00000649906; = p.T199I on NM_005827.4) | Missense Mutation (SNP) | VAF 136/280 reads (49%) | SIFT tolerated (0.13); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- SOX11 | c.332C>A p.A111D | Missense Mutation (SNP) | VAF 89/528 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SOX3 | c.138G>T p.E46D | Missense Mutation (SNP) | VAF 475/1213 reads (39%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SPOCD1 | c.952G>A p.A318T | Missense Mutation (SNP) | VAF 202/414 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.063); called by muse, varscan2
- SYNE1 | c.4435A>T p.M1479L (on ENST00000367255 / NM_182961.4; = p.M1486L on NM_033071.3) | Missense Mutation (SNP) | VAF 28/438 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- TRIM63 | c.103G>T p.V35F | Missense Mutation (SNP) | VAF 168/361 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TROAP | c.1031C>T p.S344L | Missense Mutation (SNP) | VAF 82/319 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- USH2A | c.10037C>A p.A3346E | Missense Mutation (SNP) | VAF 442/600 reads (74%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); called by muse, varscan2
- AC011448.1 | c.555C>T p.N185= | Silent (SNP) | VAF 277/513 reads (54%) | catalogued as rs369545105; called by muse, mutect2, varscan2
- ADAMTS10 | c.372C>T p.Y124= | Silent (SNP) | VAF 233/522 reads (45%) | catalogued as rs138572540; called by muse, mutect2, varscan2
- ADCY8 | c.75C>T p.G25= | Silent (SNP) | VAF 232/748 reads (31%) | called by muse, varscan2
- ARRB1 | c.1026C>T p.D342= | Silent (SNP) | VAF 279/424 reads (66%) | catalogued as rs150290364; called by muse, mutect2, varscan2
- ATP13A4 | c.3477A>G p.A1159= | Silent (SNP) | VAF 24/546 reads (4%) | catalogued as COSV100710643; called by muse, mutect2
- CACHD1 | c.2739G>A p.T913= | Silent (SNP) | VAF 94/220 reads (43%) | catalogued as rs1202602620, COSV51553609; called by muse, mutect2, varscan2
- CADPS | c.2148C>T p.C716= | Silent (SNP) | VAF 148/438 reads (34%) | catalogued as rs368353277; called by muse, mutect2, varscan2
- CDKL5 | c.2670G>T p.R890= | Silent (SNP) | VAF 220/477 reads (46%) | called by muse, mutect2, varscan2
- CTSK | c.486G>C p.L162= | Silent (SNP) | VAF 116/719 reads (16%) | called by muse, mutect2, varscan2
- DAAM1 | c.1386A>G p.L462= | Silent (SNP) | VAF 87/361 reads (24%) | catalogued as rs1214958284, COSV100658423; called by muse, mutect2, varscan2
- DCLK1 | c.213G>T p.G71= | Silent (SNP) | VAF 196/742 reads (26%) | called by mutect2, varscan2
- FAM126A | c.1335C>T p.T445= | Silent (SNP) | VAF 181/585 reads (31%) | catalogued as rs776382371; called by muse, mutect2, varscan2
- FAM189A2 | c.1263G>A p.A421= | Silent (SNP) | VAF 220/768 reads (29%) | catalogued as rs772335309; called by muse, varscan2
- FRMD6 | c.1635C>T p.L545= (on ENST00000344768 / NM_001267046.2; = p.L537= on NM_152330.4) | Silent (SNP) | VAF 298/512 reads (58%) | catalogued as rs1179548355, COSV100656348; called by muse, varscan2
- FZD10 | c.1179G>A p.A393= | Silent (SNP) | VAF 61/512 reads (12%) | catalogued as rs543088043; called by muse, varscan2
- MKNK2 | c.93C>T p.P31= | Silent (SNP) | VAF 219/536 reads (41%) | catalogued as rs919109829; called by muse, mutect2, varscan2
- MTOR | c.1023C>T p.G341= | Silent (SNP) | VAF 251/462 reads (54%) | called by muse, varscan2
- NFATC2 | c.2199G>A p.T733= | Silent (SNP) | VAF 718/976 reads (74%) | catalogued as rs558006319, COSV65354617; called by muse, varscan2
- NINL | c.2313C>T p.R771= | Silent (SNP) | VAF 774/1033 reads (75%) | catalogued as rs1292476724; called by muse, varscan2
- OGDHL | c.69C>T p.D23= | Silent (SNP) | VAF 200/639 reads (31%) | catalogued as rs761258380, COSV65103528; called by muse, varscan2
- OR51A4 | c.264G>C p.L88= | Silent (SNP) | VAF 164/530 reads (31%) | catalogued as COSV66749337; called by muse, varscan2
- OR8H2 | c.72C>A p.I24= | Silent (SNP) | VAF 211/337 reads (63%) | catalogued as COSV57943031; called by muse, mutect2, varscan2
- PDZK1IP1 | c.201C>T p.T67= | Silent (SNP) | VAF 119/259 reads (46%) | catalogued as rs138001097; called by muse, varscan2
- PGAP4 | c.549G>A p.S183= | Silent (SNP) | VAF 341/582 reads (59%) | catalogued as rs535197432, COSV66388136; called by muse, varscan2
- PLPPR5 | c.942C>A p.I314= (on ENST00000263177 / NM_001037317.2; = p.I309= on NM_001010861.3) | Silent (SNP) | VAF 12/326 reads (4%) | called by muse, mutect2
- PPP2R2A | c.627C>T p.D209= | Silent (SNP) | VAF 82/171 reads (48%) | called by muse, mutect2, varscan2
- PRSS35 | c.1029G>A p.S343= | Silent (SNP) | VAF 200/610 reads (33%) | catalogued as rs757228644, COSV63800234; called by muse, varscan2
- PZP | c.297G>T p.V99= | Silent (SNP) | VAF 13/347 reads (4%) | called by muse, mutect2
- RSPH6A | c.147C>T p.D49= | Silent (SNP) | VAF 280/512 reads (55%) | catalogued as rs1207903523; called by muse, varscan2
- SCTR | c.588C>T p.D196= | Silent (SNP) | VAF 226/590 reads (38%) | catalogued as rs746911205, COSV50026827; called by muse, mutect2, varscan2
- SEC22C | c.594T>C p.C198= | Silent (SNP) | VAF 152/475 reads (32%) | called by muse, mutect2, varscan2
- SLC1A2 | c.624C>T p.T208= | Silent (SNP) | VAF 135/443 reads (30%) | called by muse, mutect2, varscan2
- SLC9B2 | c.1288T>C p.L430= | Silent (SNP) | VAF 211/372 reads (57%) | called by muse, mutect2, varscan2
- TMEM132D | c.1878C>T p.G626= | Silent (SNP) | VAF 41/330 reads (12%) | catalogued as rs140308183; called by muse, varscan2
- TMEM184A | c.1155C>A p.P385= | Silent (SNP) | VAF 142/750 reads (19%) | called by mutect2, varscan2
- TNFRSF6B | c.483C>T p.S161= | Silent (SNP) | VAF 128/826 reads (15%) | called by muse, varscan2
- TTN | c.71559C>T p.D23853= (on ENST00000591111; = p.D16429= on NM_003319.4) | Silent (SNP) | VAF 247/674 reads (37%) | catalogued as rs370908118; ClinVar: uncertain significance / likely benign; called by muse, varscan2
- TTN | c.53181C>A p.G17727= (on ENST00000591111; = p.G10303= on NM_003319.4) | Silent (SNP) | VAF 280/482 reads (58%) | called by mutect2, varscan2
- VIPAS39 | c.78C>T p.D26= | Silent (SNP) | VAF 199/326 reads (61%) | catalogued as rs112217896; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- ARHGEF4 | chr2:130915738 G>A | 5'Flank (SNP) | VAF 414/710 reads (58%) | catalogued as rs1025906166; called by muse, varscan2
- CAPZB | c.*18C>T | 3'UTR (SNP) | VAF 128/270 reads (47%) | called by muse, varscan2
- MYOSLID | n.158G>A | RNA (SNP) | VAF 197/526 reads (37%) | catalogued as rs144141552; called by muse, mutect2, varscan2
